Somatic mutation profile of tumor specimen 0DZK5E from CCDI case PBCTTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 7.5 years (2,746 days).
Specimen 0DZK5E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9d818aa-7f5f-4a2e-a290-6857eed40717.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZK5G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9015db42-9b68-4e5f-8685-c44d5900e393

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 4, 3'UTR 1, Frame Shift Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2CD2 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 155/373 reads (42%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs567596181, COSV100297959, COSV61600211; called by muse, mutect2, varscan2
- FCHO1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.8); catalogued as rs142922726; called by muse, mutect2, varscan2
- FLG2 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 305/918 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV101165924; called by muse, mutect2, varscan2
- IPP | c.1607A>G p.Y536C | Missense Mutation (SNP) | VAF 172/205 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051855877; called by muse, mutect2, varscan2
- KMT2D | c.15924G>T p.L5308= | Splice Region (SNP) | VAF 106/207 reads (51%) | catalogued as rs779956996; called by muse, mutect2, varscan2
- MTUS2 | c.3340C>T p.R1114C (on ENST00000612955 / NM_001366650.1; = p.R93C on NM_015233.6) | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs561043824; called by muse, mutect2, varscan2
- RNLS | c.665del p.R222Pfs*12 | Frame Shift Del (DEL) | VAF 137/283 reads (48%) | catalogued as COSV104405162; called by mutect2, varscan2
- TTN | c.35061G>T p.K11687N (on ENST00000591111; = p.K10760N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/369 reads (47%) | PolyPhen benign (0.295); catalogued as COSV59871504, COSV60084503; called by mutect2, varscan2
- B4GALNT3 | c.854-1G>T p.X285_splice | Splice Site (SNP) | VAF 140/321 reads (44%) | called by muse, mutect2, varscan2
- BCLAF1 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 105/444 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNTNAP3B | c.2123C>A p.T708K | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL4A5 | c.1494G>T p.L498F | Missense Mutation (SNP) | VAF 104/104 reads (100%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO43 | c.1749G>T p.Q583H | Missense Mutation (SNP) | VAF 205/473 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHDRBS2 | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- MET | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 173/404 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE4DIP | c.4096C>A p.Q1366K | Missense Mutation (SNP) | VAF 156/484 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- POTEB3 | c.432C>A p.H144Q | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RNF216 | c.1426C>A p.Q476K (on ENST00000425013 / NM_207116.3; = p.Q533K on NM_207111.4) | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMTN | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); called by muse, mutect2
- TTC25 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 121/260 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC012488.2 | c.79C>T p.L27= | Silent (SNP) | VAF 143/324 reads (44%) | called by muse, mutect2, varscan2
- ANK1 | c.1776C>T p.G592= | Silent (SNP) | VAF 111/299 reads (37%) | catalogued as rs988065118, COSV55900609; called by muse, mutect2, varscan2
- LILRA4 | c.828C>T p.S276= | Silent (SNP) | VAF 126/256 reads (49%) | catalogued as COSV52491876, COSV52492763; called by muse, mutect2, varscan2
- TCF7L1 | c.888C>A p.A296= | Silent (SNP) | VAF 205/403 reads (51%) | called by muse, mutect2, varscan2
- TRIM48 | c.63C>A p.I21= | Silent (SNP) | VAF 222/435 reads (51%) | catalogued as COSV70161971; called by muse, mutect2, varscan2
- CDH23 | c.4845+97C>A | Intron (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- LELP1 | c.*28C>A | 3'UTR (SNP) | VAF 139/277 reads (50%) | catalogued as rs747034588; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+364G>T | Intron (SNP) | VAF 227/532 reads (43%) | called by muse, mutect2
- OBSCN | c.11660-1899G>T | Intron (SNP) | VAF 95/178 reads (53%) | called by mutect2, varscan2
- SCAI | c.1674+84A>T | Intron (SNP) | VAF 42/91 reads (46%) | called by muse, mutect2, varscan2
